Gene-level copy-number profile of tumor specimen ALCH-B3B5-TTP1-A from ALCHEMIST case ALCH-B3B5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.2 years (24,181 days).
Specimen ALCH-B3B5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0b15d1d9-88f3-4d24-a05e-6658064b6db0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3B5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/d6f55e08-2f82-4e25-bbd9-f2286a97175a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 528; copy number 1: 24,053; copy number 2: 32,669; copy number 3: 1,571; copy number 4: 72; copy number 5: 13; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–1): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr10:73,995,193–74,150,842, 3 genes (within-gene range 0–1): VCL, AL596247.1, AP3M1.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:134,520,163–134,707,349, 5 genes, copy number 5 (within-gene range 4–5): AL078590.2, FAM8A6P, AL078590.1, AL596188.1, AL121970.1.
- chr13:73,054,976–73,661,891, 9 genes, copy number 5–6: KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr17:53,353,427–53,439,721, 3 genes, copy number 5: AC005341.1, AC090079.1, AC090079.2.

Autosomal genes at a single copy (total copy number 1): 21,709. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
